Somatic mutation profile of tumor specimen 0DUXOW from CCDI case PBBWPZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Spinal cord; Age at diagnosis: 7.5 years (2,738 days).
Specimen 0DUXOW: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 677018ec-4eb9-49a2-ac50-eb362b8d3e02.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUXNS (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/58e3c74a-9ef0-439a-833a-9925ab2f41f3

The open-access MAF lists 8 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 1, Nonsense Mutation 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HOOK1 | c.1292G>A p.R431Q | Missense Mutation (SNP) | VAF 527/1205 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs756479263; called by muse, mutect2, varscan2
- LRRN3 | c.1456G>A p.V486I | Missense Mutation (SNP) | VAF 299/654 reads (46%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs543081195, COSV57824385; called by muse, mutect2, varscan2
- TXNDC5 | c.1180C>T p.R394* | Nonsense Mutation (SNP) | VAF 136/436 reads (31%) | catalogued as rs377761794; called by muse, mutect2, varscan2
- WDR87 | c.197G>A p.R66Q | Missense Mutation (SNP) | VAF 349/734 reads (48%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.46); catalogued as rs371412558; called by muse, mutect2, varscan2
- ZNF524 | c.131G>A p.R44Q | Missense Mutation (SNP) | VAF 100/369 reads (27%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as COSV55609229; called by muse, mutect2, varscan2
- ZBED5 | c.1313G>C p.G438A | Missense Mutation (SNP) | VAF 626/1342 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- COL4A3 | c.3867A>G p.G1289= | Silent (SNP) | VAF 64/680 reads (9%) | called by muse, mutect2
- FTCD | c.-25G>A | 5'UTR (SNP) | VAF 63/140 reads (45%) | called by muse, mutect2, varscan2
